Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8DU, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8DU-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Antrum)

1 - "Product of esophagus, gastrectomy and duodenum":

Adenocarcinoma:

Histological pattern observed: tubular
Histologic Grade: II - moderately differentiated
Measure the longest axis of the tumor: 7.0 cm
Ulceration: present
Involvement of: adjacent adipose tissue
Type of tumor invasion: spiculated
Inflammatory reaction: mild
Proximal and distal margins: absence of neoplastic involvement.
Neural infiltration: present
Lymphatic vascular invasion: present
Blood vascular invasion: not detected
Great omentum: absence of neoplastic involvement.

- Lymph nodes of greater curvature:

Metastasis of adenocarcinoma with lymph node capsular perforation: (2/12).

The lesser curvature lymph node:

Metastasis of adenocarcinoma with lymph node capsular perforation: (5/9).

Lymph node 12C:

Absence of neoplasia: (0/1)

Lymph node 8P:

Metastasis of adenocarcinoma with lymph node capsular perforation (1/1).

Region of the celiac trunk:

Adipose tissue uninvolved by neoplasia.

ICD-O-3

Adenocarcinoma, tubular 8211/3
Site Gastric antrum C16.3
10/11/8/13

Criteria	10/24/13	Yes	No
Tumor Malignancy History			☒

Source: NCI Genomic Data Commons file 36b57886-cbbf-4e6e-bd74-dce1d9918ccc (TCGA-VQ-A8DU.4BEF0A6E-C71D-46B8-8D81-8845F59152F9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).